Somatic mutation profile of tumor specimen TCGA-61-2111-01A (aliquot TCGA-61-2111-01A-01W-0722-08) from TCGA case TCGA-61-2111, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 61.6 years (22,517 days).
Specimen TCGA-61-2111-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fa13168a-75d4-4964-bbe8-aa53e2e53210.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-61-2111-11A (Solid Tissue Normal), aliquot TCGA-61-2111-11A-01W-0723-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e3bed7c2-594a-449f-b078-715e87e821aa

The open-access MAF lists 86 somatic variants for this specimen: 70 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 14, Nonsense Mutation 4, Intron 1, 5'UTR 1, Translation Start Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP8B1 | c.1367C>T p.T456M | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909104, CM043817, CM1510512, COSV52177697; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PPP2R1A | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 25/105 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519946, COSV59042187, COSV59042498; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.730G>T p.G244C | Missense Mutation (SNP) | VAF 136/222 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519989, CM144215, COSV52668392, COSV52676997, COSV52808251; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AP1B1 | c.2694G>T p.Q898H | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.707); catalogued as COSV100434862; called by muse, mutect2, varscan2
- ARHGAP21 | c.1661G>C p.R554P | Missense Mutation (SNP) | VAF 70/313 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV57608438; called by muse, mutect2, varscan2
- ARHGEF11 | c.4340G>A p.R1447K | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as rs1334141317, COSV100169037; called by muse, mutect2
- ASCC3 | c.5971A>G p.T1991A | Missense Mutation (SNP) | VAF 13/273 reads (5%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV100976983; called by muse, mutect2
- BEND7 | c.934A>G p.N312D | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.616); catalogued as COSV100347099; called by muse, mutect2
- CDC20 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.656); catalogued as COSV100196691; called by muse, mutect2
- CDC7 | c.185A>G p.D62G | Missense Mutation (SNP) | VAF 144/424 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as COSV52311488; called by muse, mutect2, varscan2
- CFAP43 | c.3469G>A p.E1157K | Missense Mutation (SNP) | VAF 23/195 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1489456373, COSV63851944, COSV63853785; called by muse, mutect2, varscan2
- CIAO1 | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 65/296 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.25); catalogued as rs1309976565, COSV99720561; called by muse, mutect2, varscan2
- CNKSR2 | c.2393C>T p.A798V | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs141899187, COSV54270440; called by muse, mutect2, varscan2
- COL9A2 | c.220G>C p.D74H | Missense Mutation (SNP) | VAF 8/256 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.746); catalogued as COSV101025793; called by muse, mutect2
- DCAF8L1 | c.1582A>G p.N528D | Missense Mutation (SNP) | VAF 10/257 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101491562; called by muse, mutect2
- DNMBP | c.2617C>A p.H873N | Missense Mutation (SNP) | VAF 61/703 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV60628703; called by muse, mutect2
- DOCK11 | c.4043G>A p.R1348Q | Missense Mutation (SNP) | VAF 15/224 reads (7%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.922); catalogued as rs1316979472, COSV99354902; called by muse, mutect2
- EIF2AK2 | c.46A>G p.T16A | Missense Mutation (SNP) | VAF 7/181 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV99241072; called by muse, mutect2
- ELAPOR2 | c.1778C>A p.A593D (on ENST00000450689 / NM_001142749.3; = p.A426D on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as COSV99789469; called by muse, mutect2
- GIN1 | c.1330G>C p.D444H | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV67537308; called by muse, mutect2, varscan2
- GPM6A | c.740G>T p.R247L | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.48); catalogued as COSV54553779, COSV99705819; called by muse, mutect2, varscan2
- HCFC2 | c.1553C>G p.S518C | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV99983329; called by muse, mutect2
- IL18R1 | c.1516C>G p.L506V | Missense Mutation (SNP) | VAF 20/217 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.527); catalogued as rs777647939, COSV52125606; called by muse, mutect2
- IL4I1 | c.62C>G p.S21C | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.788); catalogued as COSV62008769, COSV62010902; called by muse, mutect2
- JAZF1 | c.212G>C p.R71P | Missense Mutation (SNP) | VAF 12/179 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99387517; called by muse, mutect2
- KIF18A | c.2517C>G p.N839K | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.06); catalogued as COSV54184941; called by muse, mutect2, varscan2
- KRTAP13-1 | c.186G>T p.E62D | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV62663787; called by muse, mutect2, varscan2
- LANCL1 | c.1166C>T p.P389L | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99286494; called by muse, mutect2, varscan2
- LRRC17 | c.1243G>T p.D415Y | Missense Mutation (SNP) | VAF 19/202 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.44); catalogued as COSV99978719; called by muse, mutect2
- LZTS2 | c.700G>A p.G234R | Missense Mutation (SNP) | VAF 33/374 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as rs761447747, COSV64652249; called by muse, mutect2
- MAD2L1BP | c.209G>C p.C70S | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV100938768; called by muse, mutect2
- MGA | c.5758A>G p.T1920A (on ENST00000219905 / NM_001164273.1; = p.T1711A on NM_001080541.2) | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.05); catalogued as COSV54957749; called by muse, mutect2, varscan2
- MORC2 | c.1459C>T p.R487C (on ENST00000397641 / NM_001303256.3; = p.R425C on NM_014941.3) | Missense Mutation (SNP) | VAF 12/177 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs780264849, COSV53197987; called by muse, mutect2
- MSANTD1 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1021225291, COSV101433691; called by muse, mutect2, varscan2
- MYH9 | c.2938C>T p.Q980* | Nonsense Mutation (SNP) | VAF 16/24 reads (67%) | catalogued as COSV53389318; called by muse, mutect2, varscan2
- N6AMT1 | c.251C>G p.A84G | Missense Mutation (SNP) | VAF 12/366 reads (3%) | SIFT tolerated (0.43); PolyPhen benign (0.014); catalogued as COSV100375101; called by muse, mutect2
- NUDC | c.422G>A p.G141E | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58325730; called by muse, mutect2, varscan2
- P2RX5 | c.559del p.D187Tfs*6 | Frame Shift Del (DEL) | VAF 4/37 reads (11%) | catalogued as COSV56591255; called by mutect2, pindel
- PCDHB3 | c.1376T>C p.F459S | Missense Mutation (SNP) | VAF 125/200 reads (63%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.031); catalogued as COSV50591598; called by muse, mutect2, varscan2
- PCLO | c.10696G>C p.G3566R | Missense Mutation (SNP) | VAF 8/186 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100438762; called by muse, mutect2
- PIWIL1 | c.631T>A p.F211I | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.503); catalogued as COSV55344428, COSV55348783; called by muse, mutect2, varscan2
- PLCB1 | c.153C>G p.F51L | Missense Mutation (SNP) | VAF 19/256 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV100572373, COSV104402690; called by muse, mutect2
- PRAME | c.977C>G p.T326S | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.061); catalogued as COSV101287278, COSV67161777; called by muse, mutect2
- RANBP6 | c.1735G>A p.E579K | Missense Mutation (SNP) | VAF 56/262 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV52390316; called by muse, mutect2, varscan2
- RBM25 | c.2116G>A p.V706I | Missense Mutation (SNP) | VAF 21/220 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.421); catalogued as rs369541790; called by muse, mutect2
- RFC4 | c.91G>T p.E31* | Nonsense Mutation (SNP) | VAF 32/429 reads (7%) | catalogued as COSV99961402; called by muse, mutect2
- SALL1 | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 18/278 reads (6%) | SIFT tolerated (0.6); PolyPhen benign (0.089); catalogued as rs752432804, COSV51753014; called by muse, mutect2
- SLC25A14 | c.79C>A p.Q27K | Missense Mutation (SNP) | VAF 30/366 reads (8%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.678); catalogued as COSV54419005; called by muse, mutect2
- SLC39A5 | c.1114G>A p.G372S | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.327); catalogued as rs1461205783, COSV57192439; called by muse, mutect2, varscan2
- SLC5A11 | c.345C>G p.I115M | Missense Mutation (SNP) | VAF 52/1185 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.484); catalogued as COSV100762963; called by muse, mutect2
- SNRNP200 | c.4796C>T p.P1599L | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs762545526, COSV60487608; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ST3GAL3 | c.1106G>A p.R369Q (on ENST00000361392 / NM_174964.4; = p.R354Q on NM_006279.5) | Missense Mutation (SNP) | VAF 90/476 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.801); catalogued as rs766081620, COSV53516377; called by muse, varscan2
- STAT5B | c.1927C>G p.L643V | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV53182405; called by muse, mutect2, varscan2
- TEK | c.3317C>T p.T1106M | Missense Mutation (SNP) | VAF 29/713 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs751768682, COSV66228046; called by muse, mutect2
- TGFBR3 | c.205C>T p.L69F | Missense Mutation (SNP) | VAF 65/1145 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99283801; called by muse, mutect2
- TIMMDC1 | c.703G>T p.E235* | Nonsense Mutation (SNP) | VAF 16/518 reads (3%) | catalogued as COSV99956322; called by muse, mutect2
- TRPC6 | c.809C>A p.S270Y | Missense Mutation (SNP) | VAF 126/531 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60257476; called by muse, mutect2, varscan2
- TTC17 | c.1995G>C p.L665F | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV50011931; called by muse, mutect2, varscan2
- VEGFD | c.403C>T p.P135S | Missense Mutation (SNP) | VAF 54/429 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV52910289, COSV99938306; called by muse, mutect2, varscan2
- VSTM2L | c.404C>T p.T135M | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as rs769946306, COSV65096236; called by muse, mutect2, varscan2
- WNK4 | c.635G>C p.R212T | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV99519590; called by muse, mutect2, varscan2
- ZBTB44 | c.1007C>T p.S336F | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV63537736; called by muse, mutect2, varscan2
- ZNF354B | c.155C>T p.S52L | Missense Mutation (SNP) | VAF 26/280 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100483151; called by muse, mutect2
- ZNRD2 | c.17C>A p.A6D | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.66); PolyPhen benign (0.216); catalogued as COSV57079765; called by muse, mutect2, varscan2
- ZYG11B | c.412C>T p.L138F | Missense Mutation (SNP) | VAF 10/131 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99597889; called by muse, mutect2
- B3GAT1 | c.926T>G p.V309G | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- IGHV4-4 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- SEMA4A | c.895C>G p.L299V | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); called by mutect2, varscan2
- TUBB4B | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); called by muse, varscan2
- ZMIZ1 | c.292_293insGACCCCCTCTTCATGACAGGAACTTTTGTAT p.S98* | Nonsense Mutation (INS) | VAF 81/98 reads (83%) | called by mutect2, varscan2*
- ADAMTS16 | c.2370T>C p.N790= | Silent (SNP) | VAF 18/304 reads (6%) | catalogued as rs1221842927, COSV99943316; called by muse, mutect2
- CCDC141 | c.3529C>T p.L1177= | Silent (SNP) | VAF 29/205 reads (14%) | catalogued as rs373773937, COSV55377064; called by muse, mutect2, varscan2
- DDX56 | c.1329G>A p.R443= | Silent (SNP) | VAF 5/45 reads (11%) | called by muse, mutect2, varscan2
- FCHSD1 | c.2043G>A p.P681= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs530774288, COSV51837938; called by muse, mutect2
- GRB14 | c.1503C>T p.H501= | Silent (SNP) | VAF 26/96 reads (27%) | catalogued as COSV55740086; called by muse, mutect2, varscan2
- LHX8 | c.790T>C p.L264= | Silent (SNP) | VAF 10/228 reads (4%) | catalogued as COSV99634526; called by muse, mutect2
- NEO1 | c.2250C>T p.L750= | Silent (SNP) | VAF 11/218 reads (5%) | catalogued as rs1408214970, COSV99982910; called by muse, mutect2
- OR2M4 | c.45G>T p.L15= | Silent (SNP) | VAF 20/639 reads (3%) | catalogued as rs1325590349, COSV100140968; called by muse, mutect2
- PRMT8 | c.1107C>T p.D369= | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as COSV54216288; called by muse, varscan2
- SFXN2 | c.765C>T p.F255= | Silent (SNP) | VAF 70/1396 reads (5%) | catalogued as COSV64012954; called by muse, mutect2
- SHISAL2A | c.430C>T p.L144= | Silent (SNP) | VAF 14/190 reads (7%) | catalogued as COSV101284287; called by muse, mutect2
- TUBGCP3 | c.2217G>A p.Q739= | Silent (SNP) | VAF 14/188 reads (7%) | catalogued as COSV56191926, COSV99997337; called by muse, mutect2
- USP2 | c.1632C>T p.Y544= | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as rs781613385, COSV52728063; called by muse, mutect2, varscan2
- ZNF585B | c.1191C>G p.L397= | Silent (SNP) | VAF 9/365 reads (2%) | catalogued as COSV100459681; called by muse, mutect2
- MARCHF1 | c.-322-85645C>A | Intron (SNP) | VAF 22/264 reads (8%) | called by muse, mutect2
- VPS11 | c.-1048C>T | 5'UTR (SNP) | VAF 4/54 reads (7%) | catalogued as COSV100334034; called by muse, mutect2
